Somatic mutation profile of tumor specimen MBCProject_0128_T3_WES (aliquot MBCProject_0128_T3_WES_1) from CMI case MBCProject_0128, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 37.1 years (13,553 days).
Specimen MBCProject_0128_T3_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Bone; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2824e11-4594-4666-9deb-53bbb8cc3c4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0128_SALIVA (Saliva), aliquot MBCProject_0128_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f65fee5f-4737-4a38-9cc9-3f0fecba265b

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ESR1 | c.1613A>G p.D538G | Missense Mutation (SNP) | VAF 5/72 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52781024; called by muse, mutect2
- PIAS3 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as rs868988923, COSV65171507; called by muse, mutect2, varscan2
- PTPN23 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as rs1156669153; called by mutect2, varscan2
- HERC1 | c.6795G>A p.E2265= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV71250440; called by mutect2, varscan2
- CCDC92 | c.34+9T>C | Intron (SNP) | VAF 3/23 reads (13%) | catalogued as rs778535854; called by muse, varscan2
